Surgical pathology report (de-identified scan), TCGA case TCGA-29-1770, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1770-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1770

Surg Path

CLINICAL HISTORY:

Malignant neoplasm of the ovary.

GROSS EXAMINATION:

A. "Left tube and ovary (AF1)". Received fresh is a 13 gram, 2.5 x 1.5 x 1.3 cm ovary and a 4 x 0.5 cm fimbriated fallopian tube. The ovarian serosa exhibits 0.3 cm mucinous papillary fronds which also involve the parenchyma. The fallopian tube is grossly unremarkable. A portion of the ovary is frozen as AF1.

BLOCK SUMMARY:

A1- frozen section remnant AF1.
A2- ovary with tumor (60% of ovary submitted)
A3- fallopian tube.

B. "Right tube and ovary". Received fresh is a 3.4 x 2 x 2 cm ovary and a 4 x 0.6 cm fimbriated fallopian tube. The ovarian serosa exhibits friable, exophytic tumor (up to 0.6 cm) which involves the ovarian parenchyma. The fallopian tube is studded with multiple loosely adherent fragments of tumor, the largest of which is 1.3 cm in greatest dimension. The tubal interior is uninvolved.

BLOCK SUMMARY:

B1-B2- ovary with tumor (75% submitted).
B3- tube with serosal implant

C. "Uterus and cervix". Received fresh is a 66.5 gram uterus (7.5 x 5 x 2.8 cm). The serosa discloses multiple subserosal leiomyomata (1.3 cm). No tumor implants are noted. The endometrial cavity (1.7 cm from cornu to cornu and 2.7 cm in length) contains an atrophic endometrium (0.1 cm thick). The cervix (2.8 cm) contains a patent os, a tan herring bone mucosa and is unremarkable. The myometrium contains several leiomyoma (1.1 cm).

BLOCK SUMMARY:

C1- leiomyomata.
C2- anterior cervix and anterior endomyometrium.
C3- posterior cervix and posterior endomyometrium with leiomyoma.

D. "Omentum". Received fresh and placed in formalin is a 26 x 12 x 10 cm aggregate of fibrotic omental tissue which is diffusely involved with tumor with nodules up to 2.6 cm. The cut surface of the nodules are fleshy. Representative sections are submitted in blocks D1-D5.

INTRA OPERATIVE CONSULTATION:

A. "Left tube and ovary": AF1-adenocarcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: HYSTERECTOMY & OOPHORECTOMY

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [redacted] as required for

[page 2 of 2]
TCGA-29-1770

accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A & B. "LEFT AND RIGHT OVARIES":

TYPE: SEROUS ADENOCARCINOMA

FIGO GRADE: 2

TUMOR SIZE: 2.5 X 1.5 X 1.3 CM & 3.4 X 2 X 2 CM, RESPECTIVELY

WEIGHT: 13 & NA GRAMS

SEROUSA: INVOLVED, BILATERALLY

ADDITIONAL FINDINGS: NONE

WITH METASTATIC/IMPLANTED TUMOR, INVOLVING THE FOLLOWING SPECIMENS

A. LEFT FALLOPIAN TUBE ON SEROSA

B. RIGHT FALLOPIAN TUBE ON SEROSA PLUS LARGE NODULE WITHIN LUMEN

C. UTERUS, 66 GRAMS

SEROUSA: INVOLVED WITH TUMOR

ENDOMETRIUM: ATROPHY

MYOMETRIUM: LEIOMYOMATA, SMALL

ADENOMYOSIS, FOCAL

CERVIX: NO PATHOLOGIC DIAGNOSIS.

D. "OMENTUM": EXTENSIVE TUMOR NODULES (2.6 CM MAX)

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3f1f22af-2f07-4c5e-947a-f1363440e42e (TCGA-29-1770.05816AAC-55D2-4604-9300-E268F73338FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).